Somatic mutation profile of tumor specimen MMRF_2115_1_BM_CD138pos (aliquot MMRF_2115_1_BM_CD138pos_T1_KHS5U_L08649) from MMRF case MMRF_2115, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.4 years (24,236 days).
Specimen MMRF_2115_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 021d0e6c-e001-47f4-a031-3f3de13c500b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2115_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2115_1_PB_Whole_C2_KHS5U_L08650; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/636f59bf-52df-4100-817a-e934c6327d32

The open-access MAF lists 193 somatic variants for this specimen: 79 protein-altering or splice-affecting, 22 silent, 92 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, 3'UTR 39, Intron 29, Silent 22, 5'UTR 7, Nonsense Mutation 6, 3'Flank 6, RNA 6, 5'Flank 5, In Frame Del 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2281G>A p.D761N | Missense Mutation (SNP) | VAF 104/388 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs121913418, COSV51772923, COSV51787507; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACP5 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 93/437 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.622); catalogued as rs143362935; called by muse, mutect2, varscan2
- ARMC3 | c.1828G>A p.V610I | Missense Mutation (SNP) | VAF 293/606 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs375931697, COSV99959092; called by muse, mutect2, varscan2
- ATP8B4 | c.1877A>T p.D626V | Missense Mutation (SNP) | VAF 152/350 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs776931440; called by muse, mutect2, varscan2
- C19orf57 | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 104/676 reads (15%) | catalogued as COSV60967318; called by muse, mutect2, varscan2
- C3 | c.2083G>T p.E695* | Nonsense Mutation (SNP) | VAF 137/511 reads (27%) | catalogued as COSV55575535; called by muse, mutect2, varscan2
- CACNA2D1 | c.2528G>T p.R843I (on ENST00000356253 / NM_001366867.1; = p.R831I on NM_000722.4) | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV62396298; called by muse, mutect2, varscan2
- CCDC166 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 98/179 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV72638903; called by muse, mutect2, varscan2
- CCDC7 | c.2860G>A p.E954K | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.184); catalogued as rs753421053, COSV56543331, COSV56545707; called by muse, varscan2
- CPZ | c.514G>C p.E172Q (on ENST00000360986 / NM_001014447.3; = p.E161Q on NM_003652.3) | Missense Mutation (SNP) | VAF 107/223 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); catalogued as COSV59926087; called by muse, mutect2, varscan2
- CYP4F3 | c.1471G>A p.V491I | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as rs375318772, COSV55409460, COSV55410867; called by muse, mutect2, varscan2
- DBH | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67548992; called by muse, varscan2
- DHX30 | c.1007G>A p.R336H (on ENST00000445061 / NM_138615.3; = p.R297H on NM_014966.3) | Missense Mutation (SNP) | VAF 210/428 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs1416229407; called by muse, mutect2, varscan2
- DNAH1 | c.8816G>A p.R2939H | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs749580264, COSV70229669; ClinVar: uncertain significance; called by muse, varscan2
- FARS2 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 135/284 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863223957, COSV51165671; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHV5-51 | c.80G>C p.G27A | Missense Mutation (SNP) | VAF 208/512 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as rs530172223; called by muse, varscan2
- IGLV3-1 | c.212A>C p.K71T | Missense Mutation (SNP) | VAF 122/252 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.218); catalogued as rs537636882; called by muse, varscan2
- KIR3DL2 | c.376C>T p.L126F | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs1170096175; called by muse, mutect2, varscan2
- LOXHD1 | c.1328C>A p.S443Y | Missense Mutation (SNP) | VAF 71/286 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs373322838; called by muse, mutect2, varscan2
- LZTS2 | c.1498C>T p.R500* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | catalogued as rs745414258; called by muse, varscan2
- MBD6 | c.1156C>G p.R386G | Missense Mutation (SNP) | VAF 155/607 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.597); catalogued as rs370029120; called by muse, mutect2, varscan2
- MS4A14 | c.1678C>A p.Q560K | Missense Mutation (SNP) | VAF 268/825 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs1294164681; called by muse, mutect2, varscan2
- MUC12 | c.15522G>A p.M5174I (on ENST00000379442; = p.M5031I on NM_001164462.1) | Missense Mutation (SNP) | VAF 229/508 reads (45%) | SIFT deleterious (0.02); catalogued as rs768067010; called by muse, mutect2, varscan2
- OLFM1 | c.857C>T p.T286M (on ENST00000371793 / NM_001282611.2; = p.T268M on NM_014279.5) | Missense Mutation (SNP) | VAF 320/1193 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs372599021; called by muse, mutect2, varscan2
- OR5K4 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 318/701 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs755708185; called by muse, mutect2, varscan2
- PREX1 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 84/196 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as rs375685234; called by muse, mutect2, varscan2
- PRF1 | c.1288dup p.D430Gfs*28 | Frame Shift Ins (INS) | VAF 103/152 reads (68%) | catalogued as rs1226526104; called by mutect2, pindel, varscan2
- PTPRD | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 74/232 reads (32%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.023); catalogued as rs1249636201, COSV61972122; called by muse, mutect2, varscan2
- REST | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 95/108 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs750258882; called by muse, mutect2, varscan2
- RNFT2 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 99/449 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as rs1220221919; called by muse, mutect2, varscan2
- RPL13A | c.203G>T p.R68L | Missense Mutation (SNP) | VAF 111/380 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs764899789, COSV52621069; called by muse, mutect2, varscan2
- SCN10A | c.4094C>A p.T1365N | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748854017; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPEG | c.2975C>T p.A992V | Missense Mutation (SNP) | VAF 78/177 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.265); catalogued as rs766108579, COSV56666245; called by muse, mutect2, varscan2
- STOML2 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 92/233 reads (39%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.559); catalogued as COSV59715759; called by muse, mutect2, varscan2
- THBS2 | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 117/279 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs201885587, COSV64677097; called by muse, mutect2, varscan2
- TPTE | c.545A>G p.K182R (on ENST00000618007 / NM_199261.4; = p.K164R on NM_199259.4) | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.051); catalogued as rs750996733; called by muse, mutect2, varscan2
- VEZF1 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs1376754186; called by muse, mutect2, varscan2
- ZNF184 | c.2158C>A p.H720N | Missense Mutation (SNP) | VAF 183/381 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53003271; called by muse, mutect2, varscan2
- ZNF558 | c.927G>T p.Q309H | Missense Mutation (SNP) | VAF 132/600 reads (22%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.879); catalogued as COSV56864320; called by muse, mutect2, varscan2
- ZNRF4 | c.1111G>T p.D371Y | Missense Mutation (SNP) | VAF 368/1443 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV55773668; called by muse, mutect2, varscan2
- ADGRF1 | c.1829T>C p.F610S | Missense Mutation (SNP) | VAF 130/628 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- ADGRL1 | c.4187C>A p.S1396Y (on ENST00000340736 / NM_001008701.3; = p.S1391Y on NM_014921.5) | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- AEBP1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 178/395 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ATRNL1 | c.281A>G p.Q94R | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- C19orf57 | c.1546C>A p.L516M | Missense Mutation (SNP) | VAF 166/677 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- CDH18 | c.433T>A p.F145I | Missense Mutation (SNP) | VAF 226/352 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CNTN3 | c.1016G>T p.C339F | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- COBL | c.1576C>A p.P526T | Missense Mutation (SNP) | VAF 97/214 reads (45%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHX15 | c.1075C>T p.Q359* | Nonsense Mutation (SNP) | VAF 144/297 reads (48%) | called by muse, mutect2, varscan2
- DNM1 | c.1458G>A p.M486I | Missense Mutation (SNP) | VAF 191/652 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOCK2 | c.3298G>A p.E1100K | Missense Mutation (SNP) | VAF 122/261 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- ESRP1 | c.616_619del p.V206Ifs*20 | Frame Shift Del (DEL) | VAF 39/85 reads (46%) | called by mutect2, pindel, varscan2
- FAT1 | c.6256T>G p.Y2086D | Missense Mutation (SNP) | VAF 136/301 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GBP1 | c.947_958del p.V316_L319del | In Frame Del (DEL) | VAF 47/142 reads (33%) | called by mutect2, pindel, varscan2
- IGHA2 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 65/127 reads (51%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- IGHE | c.1230G>C p.E410D | Missense Mutation (SNP) | VAF 63/123 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- IGHV2-70D | c.287A>C p.K96T | Missense Mutation (SNP) | VAF 78/207 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, varscan2
- MAB21L2 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 287/614 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- MACC1 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 161/368 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- MARF1 | c.4505A>C p.H1502P | Missense Mutation (SNP) | VAF 183/408 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MGST3 | c.407A>G p.H136R | Missense Mutation (SNP) | VAF 161/333 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUC5B | c.3694G>A p.A1232T | Missense Mutation (SNP) | VAF 96/330 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- NACC2 | c.1633C>A p.P545T | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); called by mutect2, varscan2
- NFKB2 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 140/318 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- OR8H1 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 190/691 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PIK3C2G | c.2854C>A p.P952T (on ENST00000676171; = p.P911T on NM_004570.5) | Missense Mutation (SNP) | VAF 50/52 reads (96%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SGPP1 | c.371G>A p.S124N | Missense Mutation (SNP) | VAF 122/272 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- SLU7 | c.5C>A p.S2* | Nonsense Mutation (SNP) | VAF 339/1152 reads (29%) | called by muse, varscan2
- SPATA6L | c.814A>C p.K272Q (on ENST00000461761 / NM_001353484.2; = p.K214Q on NM_001039395.4 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 112/378 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- TFPI2 | c.632-2A>G p.X211_splice | Splice Site (SNP) | VAF 119/286 reads (42%) | called by muse, mutect2, varscan2
- TMC6 | c.110T>A p.L37H | Missense Mutation (SNP) | VAF 89/211 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TRPM6 | c.3898C>T p.L1300F | Missense Mutation (SNP) | VAF 163/480 reads (34%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRPV6 | c.716T>A p.V239E | Missense Mutation (SNP) | VAF 98/185 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- UBR2 | c.1529T>G p.L510* | Nonsense Mutation (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- VPS16 | c.77A>T p.D26V | Missense Mutation (SNP) | VAF 193/224 reads (86%) | SIFT tolerated (0.27); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF136 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 61/573 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- ZNF35 | c.1051G>A p.V351I | Missense Mutation (SNP) | VAF 396/850 reads (47%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- ZNF418 | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 107/700 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ZNF804B | c.2383A>C p.K795Q | Missense Mutation (SNP) | VAF 132/303 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- ADCY8 | c.1389C>T p.D463= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as COSV53894846; called by muse, mutect2, varscan2
- ATCAY | c.669G>A p.E223= | Silent (SNP) | VAF 124/563 reads (22%) | catalogued as COSV56654970; called by muse, mutect2, varscan2
- BAIAP2 | c.1437C>T p.P479= | Silent (SNP) | VAF 198/398 reads (50%) | catalogued as rs368718135; called by muse, mutect2, varscan2
- GPRC5B | c.1059C>T p.G353= | Silent (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.96C>T p.S32= | Silent (SNP) | VAF 132/286 reads (46%) | catalogued as rs370205939; called by muse, varscan2
- IL3 | c.264G>A p.Q88= | Silent (SNP) | VAF 151/316 reads (48%) | called by muse, mutect2, varscan2
- INPP5E | c.1584C>T p.I528= | Silent (SNP) | VAF 135/491 reads (27%) | called by muse, mutect2, varscan2
- MAFA | c.288G>A p.P96= | Silent (SNP) | VAF 23/61 reads (38%) | called by muse, mutect2, varscan2
- MTR | c.3051G>A p.L1017= | Silent (SNP) | VAF 69/360 reads (19%) | catalogued as COSV100855610; called by muse, mutect2, varscan2
- MTREX | c.1332A>T p.V444= | Silent (SNP) | VAF 42/88 reads (48%) | catalogued as COSV57929759; called by muse, mutect2, varscan2
- NBPF4 | c.1869C>T p.S623= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs2582071; called by muse, mutect2
- NFKB2 | c.642C>A p.S214= | Silent (SNP) | VAF 38/88 reads (43%) | called by muse, varscan2
- PTPRZ1 | c.1833C>T p.S611= | Silent (SNP) | VAF 112/239 reads (47%) | catalogued as rs771908516; called by muse, mutect2, varscan2
- RIMBP2 | c.705C>T p.N235= | Silent (SNP) | VAF 88/407 reads (22%) | catalogued as rs768510767, COSV55463944, COSV55465866; called by muse, mutect2, varscan2
- RPN2 | c.552T>A p.I184= | Silent (SNP) | VAF 66/129 reads (51%) | called by muse, mutect2, varscan2
- SGPP1 | c.369G>A p.V123= | Silent (SNP) | VAF 118/260 reads (45%) | called by muse, mutect2
- SLU7 | c.138C>G p.G46= | Silent (SNP) | VAF 164/598 reads (27%) | called by muse, varscan2
- TRIB3 | c.987C>T p.L329= | Silent (SNP) | VAF 14/258 reads (5%) | called by muse, mutect2
- TRMT10B | c.334C>T p.L112= | Silent (SNP) | VAF 136/403 reads (34%) | called by muse, mutect2, varscan2
- TTC23L | c.804G>A p.R268= | Silent (SNP) | VAF 123/415 reads (30%) | called by muse, mutect2, varscan2
- USH1C | c.231G>A p.L77= | Silent (SNP) | VAF 11/164 reads (7%) | called by muse, mutect2
- ZNF585A | c.807C>T p.S269= (on ENST00000292841 / NM_001288800.2; = p.S214= on NM_152655.3) | Silent (SNP) | VAF 179/529 reads (34%) | called by muse, mutect2, varscan2
- ABL2 | c.*3809del | 3'UTR (DEL) | VAF 67/195 reads (34%) | called by mutect2, pindel, varscan2
- AC018755.3 | n.130_153del | RNA (DEL) | VAF 55/220 reads (25%) | called by mutect2, pindel, varscan2
- AC098650.1 | c.*115+16839A>G | Intron (SNP) | VAF 137/326 reads (42%) | called by muse, mutect2, varscan2
- ADAM9 | c.333+603T>C | Intron (SNP) | VAF 103/217 reads (47%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.*1991del | 3'UTR (DEL) | VAF 120/278 reads (43%) | called by mutect2, varscan2
- AHRR | c.*835G>A | 3'UTR (SNP) | VAF 458/730 reads (63%) | catalogued as rs1308006616; called by muse, mutect2, varscan2
- AMOTL1 | c.*3855C>T | 3'UTR (SNP) | VAF 54/183 reads (30%) | catalogued as rs896812401; called by muse, mutect2, varscan2
- ANGPTL1 | c.*170C>T | 3'UTR (SNP) | VAF 33/178 reads (19%) | catalogued as rs1405662978; called by muse, mutect2, varscan2
- ANKRD44 | c.1100+18T>G | Intron (SNP) | VAF 389/822 reads (47%) | called by muse, mutect2, varscan2
- ANTXR2 | c.*4574C>A | 3'UTR (SNP) | VAF 68/75 reads (91%) | called by muse, mutect2, varscan2
- ARMS2 | c.*162G>A | 3'UTR (SNP) | VAF 121/276 reads (44%) | catalogued as rs7915705; called by muse, mutect2, varscan2
- ATP2C1 | c.*7T>C | 3'UTR (SNP) | VAF 27/112 reads (24%) | called by muse, mutect2, varscan2
- BABAM1 | c.786+32C>T | Intron (SNP) | VAF 21/131 reads (16%) | catalogued as rs773111639; called by muse, mutect2, varscan2
- CAPN12 | c.1815+43G>A | Intron (SNP) | VAF 247/666 reads (37%) | called by muse, mutect2, varscan2
- CCDC68 | c.-8-47C>T | Intron (SNP) | VAF 235/519 reads (45%) | called by muse, mutect2, varscan2
- CMPK2 | c.1226+276G>A | Intron (SNP) | VAF 106/235 reads (45%) | called by muse, mutect2, varscan2
- CNTNAP3B | c.1072-1463G>A | Intron (SNP) | VAF 70/212 reads (33%) | called by muse, mutect2, varscan2
- DLG4 | chr17:7219377 G>A | 5'Flank (SNP) | VAF 237/473 reads (50%) | catalogued as rs535984005; called by muse, mutect2, varscan2
- EFTUD2 | c.1719+84C>T | Intron (SNP) | VAF 23/63 reads (37%) | called by muse, mutect2, varscan2
- ENKUR | c.-213G>A | 5'UTR (SNP) | VAF 82/352 reads (23%) | called by muse, mutect2, varscan2
- FAH | c.455+9T>G | Intron (SNP) | VAF 116/983 reads (12%) | called by muse, mutect2, varscan2
- FAM118B | c.983-43T>C | Intron (SNP) | VAF 115/393 reads (29%) | called by muse, mutect2, varscan2
- FAM171B | c.*1193T>C | 3'UTR (SNP) | VAF 84/97 reads (87%) | catalogued as rs774909710; called by muse, mutect2, varscan2
- GABRA1 | chr5:161899782 A>G | 3'Flank (SNP) | VAF 93/185 reads (50%) | called by muse, mutect2, varscan2
- GBP3 | c.428+127A>T | Intron (SNP) | VAF 211/242 reads (87%) | called by muse, mutect2, varscan2
- GLIPR1L2 | c.*145C>A | 3'UTR (SNP) | VAF 70/343 reads (20%) | called by muse, mutect2, varscan2
- GPA33 | c.43+7998C>G | Intron (SNP) | VAF 64/136 reads (47%) | called by muse, mutect2, varscan2
- IFT172 | c.1325+70C>T | Intron (SNP) | VAF 39/78 reads (50%) | called by muse, mutect2, varscan2
- IGHEP1 | n.594G>C | RNA (SNP) | VAF 30/253 reads (12%) | called by muse, mutect2
- IGLL5 | c.-42T>G | 5'UTR (SNP) | VAF 78/170 reads (46%) | catalogued as rs142000285, COSV101597212; called by muse, varscan2
- IYD | c.*4620G>T | 3'UTR (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- KCNJ1 | chr11:128836959 T>C | 3'Flank (SNP) | VAF 84/288 reads (29%) | called by muse, mutect2, varscan2
- KCNK2 | c.*1384del | 3'UTR (DEL) | VAF 120/248 reads (48%) | catalogued as rs202189356, COSV67204446; called by mutect2, varscan2
- KMT2A | c.432+518A>G | Intron (SNP) | VAF 270/972 reads (28%) | called by muse, varscan2
- KRT12 | c.*43G>T | 3'UTR (SNP) | VAF 23/806 reads (3%) | called by muse, mutect2
- LIMD1 | c.*6929G>A | 3'UTR (SNP) | VAF 95/202 reads (47%) | called by muse, mutect2, varscan2
- LINGO3 | c.-26G>A | 5'UTR (SNP) | VAF 36/165 reads (22%) | called by muse, mutect2, varscan2
- LRATD1 | c.*204G>T | 3'UTR (SNP) | VAF 109/246 reads (44%) | called by muse, mutect2, varscan2
- LRRTM4 | c.1551+994T>C | Intron (SNP) | VAF 56/140 reads (40%) | called by muse, mutect2, varscan2
- LYPD1 | c.-51G>C | 5'UTR (SNP) | VAF 68/202 reads (34%) | called by muse, mutect2, varscan2
- MACC1 | chr7:20139395 A>G | 3'Flank (SNP) | VAF 156/306 reads (51%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-11329G>A | Intron (SNP) | VAF 219/442 reads (50%) | catalogued as rs778128549; called by muse, mutect2, varscan2
- MAP4K3 | c.*501T>C | 3'UTR (SNP) | VAF 94/205 reads (46%) | called by muse, mutect2, varscan2
- MAPK8IP1P2 | n.122G>A | RNA (SNP) | VAF 28/83 reads (34%) | catalogued as rs1291114098; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851379 C>T | 5'Flank (SNP) | VAF 132/260 reads (51%) | called by muse, mutect2, varscan2
- MOB1B | c.*6052A>T | 3'UTR (SNP) | VAF 8/138 reads (6%) | catalogued as rs1254930189; called by muse, mutect2
- MPHOSPH8 | chr13:19677810 T>A | 3'Flank (SNP) | VAF 131/138 reads (95%) | called by muse, mutect2, varscan2
- MT1M | c.-35A>T | 5'UTR (SNP) | VAF 33/38 reads (87%) | called by muse, mutect2, varscan2
- NCOA1 | c.*1510C>T | 3'UTR (SNP) | VAF 146/303 reads (48%) | called by muse, mutect2, varscan2
- NDUFA10 | c.1000-8310C>A | Intron (SNP) | VAF 31/69 reads (45%) | called by muse, mutect2, varscan2
- NEB | c.18826-2930G>A | Intron (SNP) | VAF 65/163 reads (40%) | catalogued as rs781581005; called by muse, mutect2
- NFATC4 | chr14:24368176 A>G | 5'Flank (SNP) | VAF 24/74 reads (32%) | called by muse, mutect2, varscan2
- NFIB | c.*5343T>A | 3'UTR (SNP) | VAF 38/224 reads (17%) | called by muse, mutect2, varscan2
- NTM-AS1 | n.2590G>T | RNA (SNP) | VAF 41/236 reads (17%) | called by muse, mutect2, varscan2
- PAPPA2 | c.*2343_*2346del | 3'UTR (DEL) | VAF 54/130 reads (42%) | called by mutect2, pindel, varscan2
- PCDH11Y | c.3129+228A>T | Intron (SNP) | VAF 270/301 reads (90%) | called by muse, mutect2, varscan2
- PDE1C | c.1892-10928T>G | Intron (SNP) | VAF 23/141 reads (16%) | called by muse, mutect2, varscan2
- PHC1P1 | n.1763C>A | RNA (SNP) | VAF 34/62 reads (55%) | called by muse, varscan2
- PIK3IP1 | c.*629T>G | 3'UTR (SNP) | VAF 69/154 reads (45%) | called by muse, mutect2, varscan2
- PKD1L2 | chr16:81139705 G>T | 5'Flank (SNP) | VAF 53/56 reads (95%) | called by muse, mutect2, varscan2
- PLEKHN1 | c.*27A>G | 3'UTR (SNP) | VAF 54/111 reads (49%) | called by muse, mutect2, varscan2
- PMS1 | c.418+478C>T | Intron (SNP) | VAF 209/338 reads (62%) | called by muse, mutect2, varscan2
- PPP1CB | c.185-297G>T | Intron (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2
- PRDM16 | c.*1135G>A | 3'UTR (SNP) | VAF 138/289 reads (48%) | catalogued as rs546244802; called by muse, mutect2, varscan2
- PRMT8 | c.-249G>T | 5'UTR (SNP) | VAF 27/117 reads (23%) | called by muse, mutect2, varscan2
- PSPN | chr19:6376474 C>G | 5'Flank (SNP) | VAF 138/582 reads (24%) | called by muse, mutect2, varscan2
- PTAR1 | c.*4514G>A | 3'UTR (SNP) | VAF 84/285 reads (29%) | called by muse, mutect2, varscan2
- RAB3GAP2 | c.115+18024_115+18026del | Intron (DEL) | VAF 168/377 reads (45%) | called by mutect2, pindel, varscan2
- RECQL5 | c.1719-153C>T | Intron (SNP) | VAF 40/70 reads (57%) | called by muse, mutect2, varscan2
- RMND5A | c.*459_*463del | 3'UTR (DEL) | VAF 71/169 reads (42%) | called by mutect2, pindel, varscan2
- RNF144A | c.*20C>T | 3'UTR (SNP) | VAF 26/50 reads (52%) | catalogued as rs770412959; called by muse, varscan2
- RNF7 | c.*1377T>C | 3'UTR (SNP) | VAF 125/284 reads (44%) | catalogued as rs569371701; called by muse, mutect2, varscan2
- RSPH3 | chr6:158976437 G>A | 3'Flank (SNP) | VAF 70/79 reads (89%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.*2513C>A | 3'UTR (SNP) | VAF 126/235 reads (54%) | called by muse, mutect2, varscan2
- SAT2 | c.119-36_119-31del | Intron (DEL) | VAF 218/564 reads (39%) | called by mutect2, pindel, varscan2
- SEMA3E | c.*3252del | 3'UTR (DEL) | VAF 81/201 reads (40%) | called by mutect2, pindel, varscan2
- SGMS2 | chr4:107914148 C>T | 3'Flank (SNP) | VAF 42/117 reads (36%) | called by muse, mutect2, varscan2
- SLC18A1 | c.*159C>T | 3'UTR (SNP) | VAF 141/169 reads (83%) | called by muse, mutect2, varscan2
- SLC22A23 | c.*467G>A | 3'UTR (SNP) | VAF 71/320 reads (22%) | called by muse, mutect2, varscan2
- SLC25A21 | c.*75G>T | 3'UTR (SNP) | VAF 281/568 reads (49%) | called by muse, mutect2, varscan2
- SPI1 | c.493+542G>T | Intron (SNP) | VAF 213/664 reads (32%) | called by muse, mutect2, varscan2
- STRN | c.*4090A>T | 3'UTR (SNP) | VAF 122/284 reads (43%) | catalogued as rs1047643983; called by muse, varscan2
- SV2C | c.*3940A>G | 3'UTR (SNP) | VAF 50/120 reads (42%) | called by muse, mutect2, varscan2
- TESK1 | c.537+156C>T | Intron (SNP) | VAF 31/86 reads (36%) | catalogued as rs577887286; called by muse, varscan2
- TSPYL4 | c.*48C>T | 3'UTR (SNP) | VAF 356/406 reads (88%) | catalogued as rs986815019; called by muse, mutect2, varscan2
- TXLNGY | n.5150_5151del | RNA (DEL) | VAF 330/449 reads (73%) | called by mutect2, pindel, varscan2
- WEE1 | c.*1044T>A | 3'UTR (SNP) | VAF 27/91 reads (30%) | catalogued as COSV100219839; called by muse, mutect2, varscan2
- ZBBX | c.*251A>C | 3'UTR (SNP) | VAF 102/213 reads (48%) | called by muse, mutect2, varscan2
- ZNF195 | c.*842G>T | 3'UTR (SNP) | VAF 58/195 reads (30%) | called by muse, mutect2, varscan2
- ZNF254 | c.-89G>T | 5'UTR (SNP) | VAF 100/479 reads (21%) | called by muse, mutect2, varscan2
- ZNF493 | c.-132+10731G>T | Intron (SNP) | VAF 23/83 reads (28%) | called by muse, mutect2, varscan2
- ZRANB2 | c.*975G>A | 3'UTR (SNP) | VAF 44/110 reads (40%) | called by muse, mutect2, varscan2
